Somatic mutation profile of tumor specimen 0DS6L2 from CCDI case PBCGPD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DS6L2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b3551ea-9ffb-4567-8742-d3c6282780a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS6LG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4118a186-c031-4114-a825-9378795733dc

The open-access MAF lists 18 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 4, Silent 3, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYS | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.015); catalogued as rs374112886; called by muse, mutect2, varscan2
- NPFFR2 | c.1412G>T p.S471I | Missense Mutation (SNP) | VAF 137/376 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.298); catalogued as COSV100440298; called by muse, mutect2, varscan2
- NUDT2 | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 98/153 reads (64%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs758284072; called by muse, varscan2
- OR8K5 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100537250; called by muse, mutect2, varscan2
- SLC22A6 | c.1677G>T p.E559D | Missense Mutation (SNP) | VAF 65/347 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.022); catalogued as COSV100842917; called by muse, mutect2, varscan2
- ADGRG4 | c.8437G>T p.A2813S | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ALOX12B | c.228C>A p.F76L | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.006); called by muse, mutect2
- SGCZ | c.488T>A p.V163E | Missense Mutation (SNP) | VAF 110/304 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- EML6 | c.3486A>T p.I1162= | Silent (SNP) | VAF 87/371 reads (23%) | called by muse, mutect2, varscan2
- FA2H | c.756G>T p.L252= | Silent (SNP) | VAF 16/287 reads (6%) | called by muse, mutect2
- SLC9A2 | c.459C>T p.A153= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as rs200268302, COSV52130590; called by muse, mutect2, varscan2
- C2 | c.989-95T>A | Intron (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- ELF1 | c.-7C>G | 5'UTR (SNP) | VAF 36/164 reads (22%) | called by muse, mutect2, varscan2
- IQCD | c.-9G>A | 5'UTR (SNP) | VAF 28/87 reads (32%) | catalogued as COSV100232279; called by mutect2, varscan2
- KCNIP2 | c.*96C>A | 3'UTR (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- NALCN | c.4906-22G>T | Intron (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
- NEIL1 | c.434+29_434+30del | Intron (DEL) | VAF 28/70 reads (40%) | called by mutect2, varscan2
- RAB5C | c.535+65T>G | Intron (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
